Somatic mutation profile of tumor specimen TCGA-2G-AAGK-01A (aliquot TCGA-2G-AAGK-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGK, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 20.2 years (7,378 days).
Specimen TCGA-2G-AAGK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d664946-b684-44a3-85a8-5cd3d201a066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGK-10A (Blood Derived Normal), aliquot TCGA-2G-AAGK-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bd17693-dc76-49cd-9189-912d1280dbb3

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC18A | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764034494; called by muse, mutect2
- KANSL1L | c.719_721del p.R240del | In Frame Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs753538972; called by pindel, varscan2
- LACTB | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.147); catalogued as rs910930306; called by muse, mutect2, varscan2
- NFATC2 | c.2193C>A p.F731L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs771443055, COSV101044902; called by mutect2, varscan2
- TTN | c.37414G>T p.D12472Y (on ENST00000591111; = p.D5048Y on NM_003319.4) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | PolyPhen benign (0.106); catalogued as COSV60024188; called by muse, mutect2, varscan2
- HORMAD1 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SACS | c.11816G>C p.G3939A | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SBNO1 | c.254C>G p.T85S (on ENST00000420886; = p.T84S on NM_018183.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- H3C15 | chr1:149850285 del AACTGAGGTGG | 5'Flank (DEL) | VAF 11/27 reads (41%) | called by mutect2, varscan2
- MIR1297 | n.10C>G | RNA (SNP) | VAF 66/222 reads (30%) | called by muse, mutect2, varscan2
